FM case AD15326 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/e78fca09-272e-40eb-a480-75e7a76c8005

Female, 70.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix; primary biopsied or resected from the appendix. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
